TCGA case TCGA-63-A5MV — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Ontario Institute for Cancer Research. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8d18e026-668b-4513-9c68-9e03b18592e3

Demographics
Sex at birth: male; Country of residence at enrollment: Canada; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; AJCC staging edition: 7th; AJCC pathologic T: T2b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,100 days (3.0 years); Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 91 days; Days to treatment end: 154 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine Tartrate; Days to treatment start: 91 days; Days to treatment end: 161 days.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 787 days (2.2 years); Disease response: Tumor Free.
- Days to follow up: 1,100 days (3.0 years); Disease response: Tumor Free.
- ECOG performance status: 0; Timepoint: Other.

Other clinical attributes
- DLCO (% of predicted): 60; FEV1/FVC after bronchodilator (%): 71; FEV1/FVC before bronchodilator (%): 66; FEV1 after bronchodilator (% of reference): 64; FEV1 before bronchodilator (% of reference): 55.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 50; Tobacco smoking onset year: 1961; Tobacco smoking quit year: 2011.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-63-A5MV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 250 mg.
  Slide TCGA-63-A5MV-01A-02-TS2: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 35; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 5.
- Sample TCGA-63-A5MV-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-63-A5MV-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Lower; Location lung parenchyma: Peripheral Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,100 days; disease-specific survival: no event (censored), 1,100 days; disease-free interval: no event (censored), 1,100 days; progression-free interval: no event (censored), 1,100 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-63-A5MV-01A-21D-A26L-01): tumor purity 0.35, ploidy 2.33, whole-genome doublings 0.
